Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAHP, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAHP-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; seminoma; diameter 7.0 cm; angio-invasion present; no invasion in rete testis; no invasion of tunica albuginea; epididymis free of tumor; surgical margin of spermatic cord free of tumor.

Date of procurement (= date of orchidectomy):

ICD-O-3

Seminoma NOS 9061/3

Site: R Testis NOS C62.9

9/3/7/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 30756f2c-4f58-4447-8870-1bf3a154e191 (TCGA-2G-AAHP.C34DA705-E103-4457-A165-5C97F6B3D9A7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).